Gene-level copy-number profile of tumor specimen TCGA-AO-A0J4-01A from TCGA case TCGA-AO-A0J4, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 41.2 years (15,052 days).
Specimen TCGA-AO-A0J4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.4883e039-c3b8-4777-a0fa-765f06006523.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A0J4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0767fd72-71d4-412b-a29b-f5f5aba3f5fa

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 1,579; copy number 2: 12,709; copy number 3: 10,640; copy number 4: 16,498; copy number 5: 10,927; copy number 6: 2,876; copy number 7: 1,817; copy number 8: 1,010; copy number 9: 866; copy number 10: 298; copy number 11: 325; copy number 12: 76; copy number 13: 42; copy number 15: 6; copy number 17: 109; copy number 20: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A0J4-01A-11D-A036-01): tumor purity 0.45, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:40,042,917–41,216,714, 23 genes (within-gene range 0–5): AC098591.2, N4BP2, RNU6-1112P, AC098591.1, AC095057.1, AC095057.3, AC095057.4, RHOH, AC095057.2, LINC02265, CHRNA9, RNU7-74P, RBM47, AC098869.2, AC098869.1, MIR4802, AC131953.2, NSUN7, ARL4AP2, APBB2, AC131953.1, Y_RNA, RNA5SP160.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,735 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,242,654–159,203,313, 579 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr1:160,775,954–163,468,605, 103 genes, copy number 9 (broad region; genes not listed).
- chr1:220,094,132–223,005,995, 63 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr7:69,026,433–70,793,506, 11 genes, copy number 12 (within-gene range 7–12): AC104688.1, RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66, AUTS2.
- chr8:62,248,591–129,683,770, 979 genes, copy number 9–20 (within-gene range 5–20) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 720. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
